Surgical pathology report (de-identified scan), TCGA case TCGA-SL-A6JA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-SL-A6JA-01A (Primary Tumor).

Pathology Report

Date of Surgery:

ICD-O-3
Adenocarcinoma, endometrial
8380/3
Site Endometrium C54.1
JW 6/28/13

Diagnosis:

Uterine cancer:

- Histologic Type: Endometrioid adenocarcinoma

- Tumor site: anterior, posterior endometrium, including lower uterine segment, with extension to involve endocervix.
- Histologic grade: FIGO grade 3 (architectural grade 2, cytologic grade 3)
- Pathologic staging (pTNM[FIGO]): pT2, pN0, pM n/a (AJCC/UICC TNM 7th edition)

Microscopic Description:

Sections demonstrate an invasive endometrioid adenocarcinoma composed of pleomorphic, atypical cells with increased nuclear: cytoplasmic ratio, prominent nucleoli and a moderate amount of eosinophilic cytoplasm. Numerous mitotic features are identified. Architecturally, the neoplasm contains foci with a solid growth pattern in >5% of the tumor. The malignant glands appear crowded and demonstrate irregular contours. Maximal depth of invasion is 1.1cm in total thickness of 1.8cm, best appreciated on frozen section material. Endocervical stromal invasion is seen. Parametrial tissue does not appear involved. The myometrium demonstrates multiple vessels with atherosclerotic changes. Lymphatic invasion is seen with a D240 immunostain. Vascular invasion is not identified with a CD31 immunostain. The bilateral ovaries and fallopian tubes are uninvolved by tumor and demonstrate atrophic features.

Diagnostic Discrepancy		
IIIFAA Discrepancy		

Source: NCI Genomic Data Commons file 7c08bc2b-77db-4206-9e50-cfb3c30263e3 (TCGA-SL-A6JA.60CDA761-5DF1-4580-AD84-1CE9A15F31F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).